Somatic mutation profile of tumor specimen TCGA-CQ-5326-01A (aliquot TCGA-CQ-5326-01A-01D-1870-08) from TCGA case TCGA-CQ-5326, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 67.0 years (24,473 days).
Specimen TCGA-CQ-5326-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29a69c2a-847c-4d44-89eb-50814883faa7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-5326-10A (Blood Derived Normal), aliquot TCGA-CQ-5326-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36b713bb-3c57-439d-b12a-b9af2a3ccd86

The open-access MAF lists 239 somatic variants for this specimen: 169 protein-altering or splice-affecting, 65 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 142, Silent 65, Nonsense Mutation 21, Splice Site 3, Intron 3, 5'Flank 2, Frame Shift Ins 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- EP300 | c.3491G>A p.C1164Y | Missense Mutation (SNP) | VAF 37/155 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54335593, COSV54335605; called by muse, mutect2, varscan2
- PFKM | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as rs121918195, CM950927, COSV100402205; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.96+2T>G p.X32_splice | Splice Site (SNP) | VAF 13/91 reads (14%) | hotspot (GDC flag); catalogued as COSV53738354; called by muse, mutect2, varscan2
- ABHD17A | c.766G>A p.E256K (on ENST00000292577 / NM_001130111.2; = p.E307K on NM_031213.4) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1381584788, COSV99171191; called by muse, mutect2
- ADAMTS20 | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs1434150093, COSV67125673, COSV67136081, COSV67136513; called by muse, mutect2
- ADGRD1 | c.1909G>A p.V637M | Missense Mutation (SNP) | VAF 56/278 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.223); catalogued as rs766209925, COSV55443327, COSV55452765; called by muse, mutect2, varscan2
- ADGRL4 | c.1084-1G>T p.X362_splice | Splice Site (SNP) | VAF 10/47 reads (21%) | catalogued as COSV100875493; called by muse, mutect2, varscan2
- AGBL5 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV100548783; called by muse, mutect2, varscan2
- AMY1C | c.1083A>T p.R361S | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.387); catalogued as rs772038719, COSV100915176; called by muse, mutect2, varscan2
- AOC3 | c.2205G>C p.E735D | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100395892; called by muse, varscan2
- ARFGAP1 | c.895G>C p.E299Q | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV100796605; called by muse, mutect2, varscan2
- ARHGEF17 | c.3977C>T p.S1326F | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV99734718; called by muse, mutect2
- BBS10 | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99674300; called by muse, mutect2, varscan2
- C6 | c.1945C>T p.P649S | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as COSV99666247; called by muse, mutect2, varscan2
- C9 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs368001255, COSV99661547; called by muse, mutect2, varscan2
- CA10 | c.786G>A p.M262I | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV53351222; called by muse, mutect2, varscan2
- CATSPERB | c.1255C>T p.R419* | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | catalogued as rs774967902, COSV99830670; called by muse, mutect2, varscan2
- CCDC158 | c.1857G>C p.K619N | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV101187127, COSV66356856; called by muse, mutect2, varscan2
- CCDC57 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.312); catalogued as COSV101051762; called by muse, mutect2, varscan2
- CDH18 | c.1225G>C p.D409H | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99931289; called by muse, mutect2, varscan2
- CDK3 | c.398T>C p.L133P | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100043720; called by muse, mutect2, varscan2
- CFAP54 | c.7161C>G p.C2387W | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100732856, COSV100733081; called by muse, mutect2, varscan2
- CIC | c.4594G>T p.E1532* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV99358720; called by muse, mutect2, varscan2
- CNTNAP1 | c.2173G>C p.D725H | Missense Mutation (SNP) | VAF 25/239 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99226037; called by muse, mutect2, varscan2
- CPPED1 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99902646; called by muse, mutect2
- CUTA | c.353A>G p.E118G (on ENST00000488034 / NM_001014840.2; = p.E95G on NM_015921.3) | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99537694; called by muse, mutect2, varscan2
- DEPDC5 | c.3860A>T p.K1287M (on ENST00000400246; = p.K1356M on NM_014662.5) | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV99834071; called by muse, mutect2, varscan2
- DGKZ | c.1628A>G p.D543G (on ENST00000454345 / NM_001105540.2; = p.D355G on NM_003646.4) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100550918; called by muse, mutect2, varscan2
- DIAPH2 | c.241C>G p.Q81E | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.153); catalogued as COSV100230114; called by muse, mutect2, varscan2
- DLG5 | c.2999C>T p.S1000F | Missense Mutation (SNP) | VAF 58/185 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs1028123408, COSV100967181; called by muse, mutect2, varscan2
- DNMT3B | c.982C>G p.Q328E | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV99140401; called by muse, mutect2, varscan2
- EHHADH | c.1598C>T p.S533F | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.342); catalogued as COSV51632051, COSV99213086; called by muse, mutect2, varscan2
- EIF1 | c.113G>C p.R38T | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100179464; called by muse, mutect2, varscan2
- ENTPD1 | c.1013G>A p.C338Y | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64603733; called by muse, mutect2
- EXOC4 | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV99551948; called by muse, mutect2, varscan2
- FAM107B | c.278C>G p.S93* | Nonsense Mutation (SNP) | VAF 64/196 reads (33%) | catalogued as rs778239622, COSV99473424, COSV99474364; called by muse, mutect2, varscan2
- FAT2 | c.1242G>C p.L414F | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as COSV99941344; called by muse, mutect2, varscan2
- FES | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 62/293 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99184602; called by muse, mutect2, varscan2
- FSD2 | c.274G>C p.D92H | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.293); catalogued as COSV100574977; called by muse, varscan2
- FSD2 | c.194G>C p.R65T | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as COSV100574978; called by muse, varscan2
- GARNL3 | c.1519G>T p.D507Y | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100149800; called by muse, mutect2, varscan2
- GIT1 | c.719A>T p.D240V | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV99837799; called by muse, mutect2, varscan2
- GPRIN2 | c.561G>C p.W187C | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs782619838, COSV100966267; called by muse, mutect2, varscan2
- H3C11 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV58899154; called by muse, varscan2
- HBP1 | c.1117A>G p.M373V | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1230046740, COSV99752911; called by muse, mutect2, varscan2
- HECW1 | c.4465G>A p.E1489K | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101222520; called by muse, mutect2, varscan2
- IGFALS | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs940549283, COSV99236297; called by muse, mutect2
- IL6ST | c.1009G>C p.D337H | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100410541; called by muse, mutect2, varscan2
- ILRUN | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 49/207 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV100927161; called by muse, mutect2, varscan2
- INCENP | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs140202170; called by muse, mutect2, varscan2
- IRX5 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.534); catalogued as rs1255566733, COSV100315577; called by muse, mutect2, varscan2
- ITGA4 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99275582; called by muse, mutect2, varscan2
- ITSN1 | c.107C>G p.S36C | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.455); catalogued as COSV101180431; called by muse, mutect2, varscan2
- KARS1 | c.307A>T p.I103F | Missense Mutation (SNP) | VAF 75/338 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.187); catalogued as COSV100093593; called by muse, mutect2, varscan2
- KBTBD2 | c.27C>G p.I9M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.221); catalogued as COSV100406324; called by muse, mutect2
- KLHL23 | c.678C>G p.I226M | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.474); catalogued as rs1489258258, COSV99775476; called by muse, mutect2, varscan2
- KLHL6 | c.1690G>A p.G564S | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100384205; called by muse, mutect2, varscan2
- LANCL1 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.684); catalogued as COSV99286067; called by muse, mutect2, varscan2
- LENG1 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.028); catalogued as rs767350761, COSV99651385; called by muse, mutect2, varscan2
- LGR6 | c.2515C>T p.R839W (on ENST00000367278 / NM_001017403.1; = p.R787W on NM_021636.3) | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.772); catalogued as rs1288456449, COSV99705812; called by muse, mutect2, varscan2
- LRRC7 | c.3949G>C p.E1317Q (on ENST00000651989 / NM_001370785.2; = p.E1284Q on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99223855, COSV99225085; called by muse, mutect2, varscan2
- LSS | c.1527dup p.H510Afs*18 | Frame Shift Ins (INS) | VAF 21/71 reads (30%) | catalogued as rs1335748816; called by mutect2, pindel, varscan2
- MACF1 | c.1639C>G p.H547D | Missense Mutation (SNP) | VAF 66/292 reads (23%) | catalogued as COSV100481763; called by muse, varscan2
- MALSU1 | c.645C>A p.F215L | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51681085, COSV99324847; called by muse, mutect2, varscan2
- MAMDC2 | c.1060G>C p.D354H | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV101015128, COSV104425802; called by muse, mutect2, varscan2
- MAMDC2 | c.1217G>C p.G406A | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV101015129, COSV65858391; called by muse, mutect2, varscan2
- MCM7 | c.1183G>C p.D395H | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as COSV100384482; called by muse, mutect2, varscan2
- MCM8 | c.41G>A p.R14K | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); catalogued as COSV99177503; called by muse, mutect2, varscan2
- MDGA2 | c.941A>G p.K314R (on ENST00000399232 / NM_001113498.2; = p.K16R on NM_182830.4) | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.331); catalogued as COSV100636080; called by muse, mutect2, varscan2
- MGAT3 | c.759C>G p.F253L | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.04); catalogued as COSV100361667; called by muse, mutect2, varscan2
- MKLN1 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as COSV100759641; called by muse, mutect2, varscan2
- MMEL1 | c.2089G>C p.E697Q | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.06); catalogued as COSV56519500; called by muse, varscan2
- MPZL3 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.695); catalogued as COSV99636083; called by muse, mutect2, varscan2
- MYPN | c.2453C>G p.S818C | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100589424; called by muse, mutect2, varscan2
- MYSM1 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV101284017; called by muse, mutect2, varscan2
- NAALAD2 | c.814G>C p.D272H | Missense Mutation (SNP) | VAF 64/254 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as COSV100427921, COSV100428983; called by muse, mutect2, varscan2
- NCOA3 | c.2144C>T p.S715F | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100506984; called by muse, mutect2, varscan2
- NEDD9 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1263322836, COSV101053344; called by muse, mutect2, varscan2
- NEFL | c.1415C>T p.S472F | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV99647791; called by muse, mutect2, varscan2
- NPAP1 | c.2144C>A p.S715Y | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.452); catalogued as COSV100274613, COSV100275432; called by muse, mutect2, varscan2
- NRXN3 | c.487G>T p.E163* (on ENST00000557594 / NM_001272020.2; = p.E795* on NM_004796.6) | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as COSV55344932, COSV99814911; called by muse, mutect2, varscan2
- NT5DC2 | c.975C>G p.I325M | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV100194433; called by muse, mutect2, varscan2
- NTSR1 | c.883G>A p.V295I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100980595; called by muse, mutect2
- OBSCN | c.3305A>G p.Q1102R | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.326); catalogued as COSV99471007; called by muse, mutect2
- OCRL | c.2083C>T p.R695* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as CM983299, COSV100843289; called by muse, mutect2, varscan2
- OR4A5 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 8/112 reads (7%) | catalogued as COSV100156917, COSV60522020; called by muse, mutect2
- OR9A4 | c.139A>T p.I47F | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV101516323; called by muse, mutect2, varscan2
- OTUB1 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as COSV99734466; called by muse, mutect2, varscan2
- OTX2 | c.575C>T p.S192L (on ENST00000408990 / NM_172337.3; = p.S200L on NM_021728.4) | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100257712; called by muse, mutect2, varscan2
- PACS1 | c.2564C>T p.S855L | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100269437; called by muse, mutect2, varscan2
- PBRM1 | c.1066G>T p.E356* | Nonsense Mutation (SNP) | VAF 89/311 reads (29%) | catalogued as COSV99966844; called by muse, mutect2, varscan2
- PCDH15 | c.4936G>T p.E1646* (on ENST00000644397 / NM_001354429.2; = p.E1588* on NM_001142771.2) | Nonsense Mutation (SNP) | VAF 19/396 reads (5%) | catalogued as COSV100902247; called by muse, mutect2
- PCDH8 | c.3055G>C p.E1019Q | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as rs1469753615, COSV100131083; called by muse, mutect2, varscan2
- PCDHGA7 | c.1964C>T p.S655L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV99528605; called by muse, mutect2, varscan2
- PDE5A | c.1142C>G p.S381C | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV53354329, COSV99308139; called by muse, mutect2, varscan2
- PKDREJ | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 62/376 reads (16%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.812); catalogued as rs1192409392, COSV53551256; called by muse, mutect2, varscan2
- PKP3 | c.1170C>G p.Y390* | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as COSV100520645; called by muse, mutect2, varscan2
- PLEC | c.763G>T p.V255L (on ENST00000322810 / NM_201380.4; = p.V145L on NM_000445.5) | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100509279; called by muse, mutect2, varscan2
- PPFIA2 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV61043650; called by muse, mutect2, varscan2
- PPIG | c.1841G>A p.G614E | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV99644058; called by muse, mutect2, varscan2
- PPIG | c.1950G>C p.K650N | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.083); catalogued as COSV99644060; called by muse, mutect2
- PPP1R3D | c.798C>G p.Y266* | Nonsense Mutation (SNP) | VAF 21/63 reads (33%) | catalogued as COSV100674343; called by muse, mutect2, varscan2
- PPP2R3A | c.442T>C p.S148P | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.023); catalogued as COSV53860589; called by muse, mutect2, varscan2
- PRDM16 | c.2704G>T p.E902* | Nonsense Mutation (SNP) | VAF 64/322 reads (20%) | catalogued as COSV99575181; called by muse, mutect2, varscan2
- PTPRN | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV99833576; called by muse, mutect2, varscan2
- RBL1 | c.703C>T p.H235Y | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.492); catalogued as COSV100726834; called by muse, mutect2, varscan2
- RBM26 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.541); catalogued as rs143505765; called by muse, mutect2, varscan2
- REV3L | c.2374C>T p.Q792* | Nonsense Mutation (SNP) | VAF 27/163 reads (17%) | catalogued as COSV100724728; called by muse, mutect2, varscan2
- RIN2 | c.377A>G p.Y126C (on ENST00000255006 / NM_001242581.1; = p.Y77C on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99656520; called by muse, mutect2, varscan2
- RIOK3 | c.809G>T p.G270V | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100259099; called by muse, mutect2, varscan2
- RNF185 | c.331C>G p.Q111E | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.585); catalogued as COSV99839576; called by muse, mutect2, varscan2
- RUSC1 | c.567G>T p.Q189H | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.962); catalogued as COSV99429349; called by muse, mutect2, varscan2
- SECISBP2 | c.2515G>A p.E839K | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100357820; called by muse, mutect2, varscan2
- SENP6 | c.1073C>T p.S358L | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV100518892; called by muse, mutect2, varscan2
- SERPIND1 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV99299901; called by muse, mutect2, varscan2
- SF3B3 | c.2324A>G p.N775S | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.358); catalogued as COSV100209514; called by muse, mutect2, varscan2
- SIGLEC9 | c.832G>T p.D278Y | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99142371; called by muse, mutect2, varscan2
- SLC15A2 | c.829C>T p.R277* | Nonsense Mutation (SNP) | VAF 22/65 reads (34%) | catalogued as rs145317059; called by muse, mutect2, varscan2
- SLC26A5 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs773574721, COSV59702635; called by muse, mutect2, varscan2
- SLC2A14 | c.617A>G p.E206G | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV100533421; called by muse, mutect2
- SLX4 | c.5338G>A p.E1780K | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as COSV53560553; called by muse, mutect2, varscan2
- SMARCA4 | c.4229C>T p.S1410L | Missense Mutation (SNP) | VAF 114/183 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV100758015, COSV60791862; called by muse, mutect2, varscan2
- SMARCC2 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1565902568, COSV57215359; called by muse, mutect2
- SORL1 | c.5167-1G>A p.X1723_splice | Splice Site (SNP) | VAF 29/51 reads (57%) | catalogued as COSV99492556, COSV99492984; called by muse, mutect2, varscan2
- SOX6 | c.2047G>A p.E683K (on ENST00000528429 / NM_001145819.2; = p.E656K on NM_017508.3) | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100321075; called by muse, mutect2, varscan2
- SPTAN1 | c.2648G>A p.R883Q | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.19); catalogued as rs375111710, COSV100823163; called by muse, mutect2, varscan2
- SRRM2 | c.2339C>T p.S780L | Missense Mutation (SNP) | VAF 76/446 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); catalogued as COSV100069951; called by muse, mutect2, varscan2
- SRRM3 | c.720G>C p.K240N | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV100418535; called by muse, mutect2, varscan2
- STAC3 | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as rs777991873, COSV100234412; called by muse, mutect2, varscan2
- STK31 | c.274G>C p.D92H | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100669044; called by muse, mutect2, varscan2
- SYBU | c.538C>T p.P180S (on ENST00000276646 / NM_001099754.2; = p.P179S on NM_017786.6) | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.181); catalogued as COSV99405574; called by muse, mutect2, varscan2
- TANC1 | c.872C>G p.S291* | Nonsense Mutation (SNP) | VAF 20/72 reads (28%) | catalogued as COSV99712876; called by muse, mutect2, varscan2
- TBC1D22A | c.500C>G p.S167C | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as COSV100452504; called by muse, mutect2, varscan2
- TBL3 | c.874G>C p.G292R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100224628; called by muse, mutect2, varscan2
- TCAF1 | c.531T>A p.S177R | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100584520; called by muse, mutect2, varscan2
- TCIRG1 | c.2384C>A p.S795* | Nonsense Mutation (SNP) | VAF 37/143 reads (26%) | catalogued as COSV99693024; called by muse, mutect2, varscan2
- THSD7A | c.3136C>T p.R1046C | Missense Mutation (SNP) | VAF 67/311 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as rs370952825; called by muse, mutect2, varscan2
- TJP3 | c.2478G>T p.E826D | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as rs551071457, COSV99515633; called by muse, mutect2, varscan2
- TMEM132E | c.2451C>G p.I817M (on ENST00000321639; = p.I907M on NM_001304438.2) | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100395874; called by muse, mutect2, varscan2
- TMEM186 | c.171G>C p.W57C | Missense Mutation (SNP) | VAF 27/266 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.054); catalogued as rs746207141, COSV99191099; called by muse, mutect2, varscan2
- TMEM45A | c.412T>G p.F138V | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100057998; called by muse, mutect2, varscan2
- TRDN | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV100520541; called by muse, mutect2, varscan2
- TRIL | c.739C>G p.R247G | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV100538644, COSV59866836; called by muse, mutect2, varscan2
- TRPV3 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs748594064, COSV56790523; ClinVar: likely benign; called by muse, mutect2, varscan2
- TRPV4 | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 23/85 reads (27%) | catalogued as rs1341025285, COSV99924259; called by muse, mutect2, varscan2
- TSKU | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.86); PolyPhen benign (0.009); catalogued as COSV100289927; called by muse, mutect2
- TSR3 | c.901G>T p.E301* | Nonsense Mutation (SNP) | VAF 148/624 reads (24%) | catalogued as COSV99136099; called by muse, mutect2, varscan2
- TUBGCP4 | c.1039G>T p.E347* | Nonsense Mutation (SNP) | VAF 38/227 reads (17%) | catalogued as COSV53017797; called by muse, mutect2, varscan2
- UBR3 | c.4600C>T p.H1534Y | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV99772918; called by muse, mutect2, varscan2
- UMOD | c.1730A>G p.K577R | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.405); catalogued as COSV100207909; called by muse, mutect2, varscan2
- VPS52 | c.310C>G p.Q104E | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV101460401; called by muse, mutect2, varscan2
- WASHC5 | c.2968G>C p.D990H | Missense Mutation (SNP) | VAF 63/237 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100572412; called by muse, mutect2, varscan2
- WDR90 | c.4738G>C p.E1580Q | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.057); catalogued as COSV99552502; called by muse, mutect2, varscan2
- WNK2 | c.5128G>A p.V1710I (on ENST00000297954 / NM_001282394.1; = p.V1673I on NM_006648.3) | Missense Mutation (SNP) | VAF 81/184 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.027); catalogued as rs140544829; called by muse, mutect2, varscan2
- YARS1 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.568); catalogued as COSV100993208; called by muse, mutect2, varscan2
- ZC3H3 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs369560785; called by muse, mutect2, varscan2
- ZIC1 | c.586G>A p.G196S | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.275); catalogued as rs764570223, COSV51556964; called by muse, mutect2, varscan2
- ZNF3 | c.907C>G p.Q303E | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV99447043; called by muse, mutect2, varscan2
- ZNF439 | c.772C>T p.R258* | Nonsense Mutation (SNP) | VAF 71/140 reads (51%) | catalogued as rs535252484, COSV58308421; called by muse, mutect2, varscan2
- ZNF707 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs782101534, COSV100690485; called by muse, mutect2, varscan2
- ZNF791 | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 43/229 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs997432551, COSV100588992; called by muse, mutect2, varscan2
- ZPR1 | c.1345G>C p.E449Q | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1422633091, COSV99911119; called by muse, mutect2, varscan2
- ZRANB1 | c.1009C>G p.Q337E | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.185); catalogued as COSV100669034; called by muse, mutect2, varscan2
- ZUP1 | c.465A>T p.E155D | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.444); catalogued as COSV100884956; called by muse, mutect2, varscan2
- ZW10 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99562375; called by muse, mutect2, varscan2
- TTN | c.14434_14438del p.L4812Vfs*8 (on ENST00000591111; = p.L3885Vfs*8 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 33/245 reads (13%) | called by mutect2, pindel, varscan2
- USF3 | c.3361dup p.C1121Lfs*2 | Frame Shift Ins (INS) | VAF 30/179 reads (17%) | called by mutect2, pindel, varscan2
- ABCB9 | c.444G>A p.E148= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99757495; called by muse, mutect2, varscan2
- ACTR2 | c.988T>C p.L330= | Silent (SNP) | VAF 47/176 reads (27%) | catalogued as COSV99573631; called by muse, mutect2, varscan2
- ADGRF5 | c.3492C>G p.L1164= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV99344665; called by muse, mutect2, varscan2
- ARSD | c.357C>T p.N119= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as rs201773531, COSV99471888; called by muse, mutect2, varscan2
- AUTS2 | c.3718C>T p.L1240= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV61386755; called by muse, mutect2, varscan2
- BACE1 | c.201G>C p.L67= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100474767; called by muse, mutect2
- BMPER | c.1308C>G p.L436= | Silent (SNP) | VAF 27/138 reads (20%) | catalogued as COSV99778610; called by muse, mutect2, varscan2
- BORA | c.1200G>A p.S400= (on ENST00000613797; = p.S325= on NM_024808.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/131 reads (20%) | catalogued as rs748261221, COSV100909615; called by muse, mutect2, varscan2
- BRCA1 | c.297G>A p.L99= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV100523136; called by muse, mutect2, varscan2
- CES1 | c.1272G>C p.V424= (on ENST00000361503 / NM_001025194.2; = p.V423= on NM_001266.5) | Silent (SNP) | VAF 37/160 reads (23%) | catalogued as COSV100828521; called by muse, mutect2, varscan2
- CNOT11 | c.879T>C p.I293= | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as COSV99179214; called by muse, mutect2, varscan2
- CPD | c.3675G>A p.K1225= | Silent (SNP) | VAF 46/173 reads (27%) | catalogued as COSV99852332; called by muse, mutect2, varscan2
- CPEB4 | c.1246C>T p.L416= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as COSV99436565; called by muse, mutect2, varscan2
- DCAF12L1 | c.963C>T p.Y321= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV64422577; called by muse, mutect2, varscan2
- FAM117A | c.618C>T p.L206= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV99544385; called by muse, mutect2
- FAM78B | c.675G>A p.R225= | Silent (SNP) | VAF 21/122 reads (17%) | catalogued as COSV100597286; called by muse, mutect2, varscan2
- FOLH1 | c.1386G>A p.L462= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV99922547, COSV99923211; called by muse, mutect2, varscan2
- GART | c.594G>A p.V198= | Silent (SNP) | VAF 44/272 reads (16%) | catalogued as COSV100738107; called by muse, mutect2, varscan2
- GPKOW | c.87G>C p.R29= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV50242309, COSV99332439; called by muse, mutect2, varscan2
- GSTO1 | c.60G>A p.P20= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV100866889; called by muse, mutect2, varscan2
- HTT | c.7191C>T p.I2397= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as COSV100750268; called by muse, mutect2, varscan2
- IFT172 | c.3066G>A p.K1022= | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as rs1187626381, COSV99561545; called by muse, mutect2, varscan2
- KIF1B | c.5061C>T p.L1687= (on ENST00000377086 / NM_001365952.1; = p.L1641= on NM_015074.3) | Silent (SNP) | VAF 65/180 reads (36%) | catalogued as COSV99822227; called by muse, mutect2, varscan2
- L3MBTL1 | c.1002G>A p.L334= (on ENST00000418998 / NM_001377303.1; = p.L244= on NM_015478.7) | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100916871; called by muse, mutect2, varscan2
- LHFPL5 | c.96C>T p.L32= | Silent (SNP) | VAF 39/153 reads (25%) | catalogued as COSV100798910; called by muse, mutect2, varscan2
- LRP5 | c.3726C>G p.V1242= | Silent (SNP) | VAF 17/130 reads (13%) | catalogued as COSV99591185; called by muse, mutect2, varscan2
- MAN1C1 | c.156C>G p.L52= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV99847659, COSV99848962; called by muse, varscan2
- MEP1A | c.693G>A p.K231= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as rs1235109964, COSV100042217; called by muse, mutect2, varscan2
- NAIF1 | c.465C>T p.L155= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as rs887126439, COSV100895693; called by muse, mutect2
- NIF3L1 | c.354G>A p.E118= (on ENST00000409020 / NM_001369444.1; = p.E91= on NM_021824.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 27/126 reads (21%) | catalogued as COSV99626516; called by muse, mutect2, varscan2
- NKX6-1 | c.969C>T p.D323= | Silent (SNP) | VAF 33/125 reads (26%) | catalogued as rs1244493139, COSV55685455, COSV99879868; called by muse, mutect2, varscan2
- NPBWR2 | c.180G>C p.L60= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV100871046; called by muse, mutect2, varscan2
- NUP62CL | c.554G>A p.*185= | Silent (SNP) | VAF 46/100 reads (46%) | catalogued as COSV100990917; called by muse, mutect2, varscan2
- OR2A2 | c.348G>A p.V116= | Silent (SNP) | VAF 51/154 reads (33%) | catalogued as COSV101286608, COSV68871866; called by muse, mutect2, varscan2
- PAK1IP1 | c.813C>A p.I271= | Silent (SNP) | VAF 33/170 reads (19%) | catalogued as COSV101093307, COSV65435500; called by muse, mutect2, varscan2
- PCDH15 | c.2130C>G p.V710= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV100213486; called by muse, mutect2, varscan2
- PGK1 | c.69C>G p.V23= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as COSV100965279; called by muse, mutect2, varscan2
- PITPNM1 | c.6C>A p.L2= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV100039300; called by muse, mutect2, varscan2
- PKD2L1 | c.1377C>T p.F459= | Silent (SNP) | VAF 30/190 reads (16%) | catalogued as COSV100559240; called by muse, mutect2, varscan2
- PLEKHG5 | c.2478C>G p.L826= (on ENST00000400915 / NM_001042663.3; = p.L789= on NM_020631.6) | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV100555855, COSV100557126; called by muse, mutect2, varscan2
- PPM1G | c.273G>A p.Q91= | Silent (SNP) | VAF 73/336 reads (22%) | catalogued as rs1296277520, COSV59769472; called by muse, mutect2, varscan2
- PRKCZ | c.597C>T p.N199= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as rs150712752; called by muse, mutect2, varscan2
- PSME4 | c.4812C>T p.F1604= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV101122157; called by muse, mutect2, varscan2
- PTBP2 | c.297G>C p.L99= (on ENST00000426398 / NM_001300986.2; = p.L91= on NM_021190.4) | Silent (SNP) | VAF 33/119 reads (28%) | catalogued as COSV100930155, COSV100930204; called by muse, mutect2, varscan2
- PTBP3 | c.1653A>G p.T551= | Silent (SNP) | VAF 77/162 reads (48%) | catalogued as COSV100533932; called by muse, mutect2, varscan2
- PTGDR2 | c.339C>G p.L113= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV57125778, COSV99920019; called by muse, mutect2
- RAPGEF1 | c.1566C>T p.V522= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as rs367643811, COSV64702532; called by muse, mutect2, varscan2
- RBP3 | c.432G>C p.L144= | Silent (SNP) | VAF 21/105 reads (20%) | called by muse, mutect2, varscan2
- RPA1 | c.1254A>G p.E418= | Silent (SNP) | VAF 45/185 reads (24%) | catalogued as COSV99627585; called by muse, mutect2, varscan2
- SAP30BP | c.468G>A p.K156= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV99502625; called by muse, mutect2, varscan2
- SHANK3 | c.1539C>T p.F513= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs1039575293, COSV99435947; called by muse, mutect2, varscan2
- SLC18A3 | c.414G>C p.V138= | Silent (SNP) | VAF 32/125 reads (26%) | catalogued as COSV100339555; called by muse, mutect2, varscan2
- SMARCA4 | c.4167C>G p.L1389= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as COSV100758014; called by muse, mutect2, varscan2
- SPRR2B | c.207G>A p.P69= | Silent (SNP) | VAF 67/266 reads (25%) | catalogued as rs541636188, COSV58797504; called by muse, mutect2, varscan2
- STAT1 | c.1590C>T p.N530= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as rs552751565, COSV100738387; called by muse, mutect2, varscan2
- STMN2 | c.539G>A p.*180= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs1290627138, COSV99625985; called by muse, mutect2, varscan2
- TEX29 | c.69T>C p.V23= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as COSV99365895; called by muse, mutect2, varscan2
- TMEM59L | c.756C>T p.D252= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV99449862; called by muse, mutect2, varscan2
- TRIM58 | c.618G>A p.A206= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as rs147052726; called by muse, mutect2, varscan2
- TTN | c.88509G>A p.R29503= (on ENST00000591111; = p.R22079= on NM_003319.4) | Silent (SNP) | VAF 77/297 reads (26%) | catalogued as rs377261293, COSV100589652, COSV100589831; called by muse, mutect2, varscan2
- UBQLN3 | c.1383T>C p.S461= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV100293260; called by muse, mutect2, varscan2
- VPS33A | c.228G>A p.V76= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV99931171; called by muse, mutect2, varscan2
- YIF1B | c.99C>T p.A33= (on ENST00000339413 / NM_001039673.3; = p.A18= on NM_001039671.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs761403759, COSV100007763; called by muse, mutect2, varscan2
- ZNF12 | c.1764G>A p.Q588= (on ENST00000405858 / NM_016265.4; = p.Q550= on NM_006956.3) | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV100703527; called by muse, mutect2, varscan2
- ZNF208 | c.1821A>G p.K607= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as rs1348216362, COSV68100036, COSV68100302, COSV68110381; called by muse, varscan2
- ATP6V1G2 | chr6:31548367 G>A | 5'Flank (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100385317; called by muse, mutect2, varscan2
- BTN2A3P | n.1448-407C>T | Intron (SNP) | VAF 19/176 reads (11%) | catalogued as rs755282692; called by muse, mutect2, varscan2
- CEP170 | c.4059+19G>A | Intron (SNP) | VAF 14/74 reads (19%) | catalogued as COSV100316244; called by mutect2, varscan2
- H2BP2 | n.1061+576A>T | Intron (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
- PPP3R1 | chr2:68261223 C>G | 5'Flank (SNP) | VAF 18/77 reads (23%) | called by muse, mutect2, varscan2
